Gene-level copy-number profile of tumor specimen TCGA-61-1919-01A from TCGA case TCGA-61-1919, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 58.0 years (21,199 days).
Specimen TCGA-61-1919-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.098abc3c-1001-415f-847a-53bfee74ab79.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1919-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a713549f-6590-42ed-bf45-45094497f409

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 2: 3,505; copy number 3: 9,553; copy number 4: 16,850; copy number 5: 12,789; copy number 6: 7,209; copy number 7: 5,887; copy number 8: 542; copy number 9: 1,629; copy number 10: 1,021; copy number 11: 698; copy number 12: 40; copy number 14: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1919-01A-01D-0648-01): tumor purity 0.66, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,403 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,089,291–151,583,583, 483 genes, copy number 9–10 (within-gene range 5–10) (broad region; genes not listed).
- chr3:162,486,541–162,486,949, 1 gene, copy number 12: TOMM22P6.
- chr3:166,160,021–166,181,820, 5 genes, copy number 11: MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2.
- chr3:167,239,843–186,585,800, 341 genes, copy number 9–11 (broad region; genes not listed).
- chr3:186,581,995–186,630,211, 4 genes, copy number 9: AC068631.2, AC068631.3, AHSG, Metazoa_SRP.
- chr5:52,930,606–53,127,673, 6 genes, copy number 9: AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1.
- chr6:167,607–32,981,505, 958 genes, copy number 9–10 (broad region; genes not listed).
- chr7:123,452,193–124,647,822, 22 genes, copy number 9: IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P.
- chr7:126,378,970–144,451,817, 512 genes, copy number 9–10 (broad region; genes not listed).
- chr8:92,351,912–145,066,685, 859 genes, copy number 9–12 (broad region; genes not listed).
- chr12:18,683,169–28,825,831, 169 genes, copy number 9–10 (broad region; genes not listed).
- chr18:26,655,737–27,190,698, 1 gene, copy number 12 (within-gene range 8–12): AQP4-AS1.
- chr18:26,822,341–30,414,073, 27 genes, copy number 12: AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F.
- chr19:29,698,886–30,228,715, 15 genes, copy number 14: C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
